Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A684, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A684-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #: 2
SEX: F

PROCEDURE: SPGD

VERIFIED BY:

1. "Left adrenal." Received fresh in a medium container is a 19 gm, 4.2 x 3.2 x 3.2 cm gray-tan, bright yellow foci, disrupted and previously incised, encapsulated tumor. Cut surfaces show friable, pink-tan and focally hemorrhagic tissue with a cyst wall up to 0.1 cm thick. Cut surfaces also demonstrate a normal appearing adrenal gland (3.0 x 1.5 x 0.5 cm), densely adhered to the capsule of the tumor.
1A. Tumor. Frozen section control.
1B-E. Additional tumor including sections of adhered normal adrenal.

FROZEN SECTION REPORT

1. Pheochromocytoma.

I, , have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE: SPDX

VERIFIED BY:

1. Left adrenal, resection: Pheochromocytoma (4.3 cm).

I, , the signing staff pathologist, have personally examined and interpreted the slides from this case.

Source: NCI Genomic Data Commons file ef8202bb-d41a-4cfe-ac2b-414be12597f1 (TCGA-RW-A684.CCA32F0F-E00C-4A08-82D4-0E17A77B4D8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).